Gene-level copy-number profile of tumor specimen ALCH-B0E8-TTP1-A from ALCHEMIST case ALCH-B0E8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.5 years (24,665 days).
Specimen ALCH-B0E8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f88d5b39-a970-4593-a0ba-7c250d9d0c01.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0E8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/60c913a0-260b-49be-b912-ad9d370b76cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 5,952; copy number 2: 49,008; copy number 3: 3,317; copy number 4: 7; copy number 6: 2; copy number 9: 1; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,100,236–90,173,414, 5 genes (within-gene range 0–4): IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-12, IGKV3D-11.
- chr2:90,309,230–91,621,421, 7 genes (within-gene range 0–2): AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,686,102–91,781,169, 6 genes: AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr2:176,077,472–176,102,489, 3 genes: EVX2, HOXD13, HOXD12.
- chr3:75,395,188–75,538,029, 7 genes: LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr9:114,155,537–114,312,511, 2 genes: COL27A1, MIR455.
- chr14:93,718,298–93,788,485, 1 gene: PRIMA1.
- chr15:28,857,882–28,858,398, 1 gene (within-gene range 0–2): AC174071.1.
- chr15:64,815,632–64,825,668, 1 gene: PIF1.
- chr21:7,744,962–13,120,807, 74 genes (broad region; genes not listed).
- chr22:43,038,585–43,089,419, 2 genes: TTLL1-AS1, TTLL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,393,480–18,400,961, 1 gene, copy number 9: TBC1D3P4.
- chr17:18,426,861–18,442,895, 2 genes, copy number 15: KRT17P2, KRT16P1.
- chr17:18,476,737–18,506,313, 2 genes, copy number 6: LGALS9C, NOS2P2.

Autosomal genes at a single copy (total copy number 1): 5,936. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
